MMRF case MMRF_2038 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/798c8e5f-360a-48ac-bed1-4f49a186c7e0

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 37 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 37.4 years (13,675 days); ISS stage: III; Days to last known disease status: 1,002 days (2.7 years); Days to last follow up: 1,002 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 92 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 34 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 94 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 35 days; Days to treatment end: 94 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 128 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 124 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 124 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Dexamethasone + Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 158 days; Days to treatment end: 158 days.
   Treatment given: Therapeutic agents: Dexamethasone + Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 164 days; Days to treatment end: 164 days.
   Treatment given: Therapeutic agents: Dexamethasone + Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 168 days; Days to treatment end: 168 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 169 days; Days to treatment end: 169 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 275 days; Days to treatment end: 666 days (1.8 years).
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 275 days; Days to treatment end: 409 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 539 days (1.5 years); Days to treatment end: 632 days (1.7 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 698 days (1.9 years); Days to treatment end: 719 days (2.0 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 732 days (2.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,002.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 3): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5250 mg/dL; Beta 2 Microglobulin 15.2 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 3.41 mmol/L; Leukocytes 10.1 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 1280 µmol/L; Blood Urea Nitrogen 35 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.6 g/dL; Glucose 4.46 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 80 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 671 mg/dL; Immunoglobulin G 0.82 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 68 ×10⁹/L; Creatinine 537 µmol/L; Blood Urea Nitrogen 20 mmol/L; Calcium 2.28 mmol/L; Albumin 51 g/L; Total Protein 5.8 g/dL; Glucose 5.94 mmol/L.
- Day 182 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.14 mg/dL; Immunoglobulin G 4.28 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 0.05 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 443 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 5.7 g/dL; Glucose 4.73 mmol/L.
- Day 254 (ECOG 0): M Protein 0 g/dL; Beta 2 Microglobulin 5.1 µg/mL; Lactate Dehydrogenase 1.65 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 346 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 5.5 g/dL; Glucose 4.9 mmol/L.
- Day 339 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Hemoglobin 6.7 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 90 ×10⁹/L; Creatinine 292 µmol/L; Blood Urea Nitrogen 15.4 mmol/L; Calcium 2.33 mmol/L; Glucose 5.72 mmol/L.
- Day 448 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 295 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.38 mmol/L; Glucose 5.01 mmol/L.
- Day 541 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.27 mg/dL; Immunoglobulin G 6.27 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 1.73 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 76 ×10⁹/L; Creatinine 271 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 5.9 g/dL; Glucose 5.45 mmol/L.
- Day 632 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.91 mg/dL; Hemoglobin 6.32 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 281 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.28 mmol/L.
- Day 674 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 7.64 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 232 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.28 mmol/L.
- Day 791 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 219 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.38 mmol/L; Albumin 48 g/L; Total Protein 6.9 g/dL; Glucose 5.61 mmol/L.
- Day 911 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 7.68 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 212 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.
- Day 974 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 208 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.34 mmol/L.

Other clinical attributes
- Day -3: Weight: 58 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2038_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_2038_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
